Gene-level copy-number profile of tumor specimen C3N-00294-02 from CPTAC case C3N-00294, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 57.9 years (21,155 days).
Specimen C3N-00294-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6592c3ce-b4de-4216-a8cb-ad6839ad17c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00294-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/6749d5f5-893f-47e7-9b71-669fc54997da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,614; copy number 2: 43,628; copy number 3: 6,345; copy number 4: 5,955; copy number 5: 335; copy number 6: 1; copy number 7: 6; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:722,092–810,065, 6 genes (within-gene range 0–1): CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6.
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr8:12,043,506–12,115,516, 5 genes: DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 341 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes, copy number 5–7 (within-gene range 2–7): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr5:177,809,407–177,950,732, 1 gene, copy number 5 (within-gene range 4–5): AC106795.1.
- chr5:177,856,262–178,232,802, 15 genes, copy number 5: AC140125.3, AC106795.3, AC106795.2, AC106795.5, SUDS3P1, PROP1, FAM153CP, AC136632.1, N4BP3, RMND5B, NHP2, AC136632.2, GMCL2, HNRNPAB, PHYKPL.
- chr7:37,032–20,314,512, 317 genes, copy number 5 (broad region; genes not listed).
- chr21:44,200,602–44,244,993, 4 genes, copy number 7–8: AP001057.1, ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 1,426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
